TCGA case TCGA-24-1603 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/19427350-619b-4b9c-a3ba-37f667bb2843

Demographics
Sex at birth: female; Race: white; Age at index: 53 years; Vital status: Dead; Days to death: 2,742 days (7.5 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,681 days); Year of diagnosis: 1996; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIB; Tumor grade: G3; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,107 days (3.0 years); Days to treatment end: 1,181 days (3.2 years); Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,356 days (3.7 years); Days to treatment end: 1,516 days (4.2 years); Number of cycles: 8; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride + Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,899 days (5.2 years); Days to treatment end: 1,991 days (5.5 years); Number of cycles: 9; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,022 days (5.5 years); Days to treatment end: 2,203 days (6.0 years); Number of cycles: 28; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,234 days (6.1 years); Days to treatment end: 2,448 days (6.7 years); Number of cycles: 9; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,568 days (7.0 years); Days to treatment end: 2,629 days (7.2 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,629 days (7.2 years); Days to treatment end: 2,629 days (7.2 years); Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment end: 1,853 days (5.1 years); Number of cycles: 9; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 56.6 years (20,673 days); Days to diagnosis: 992 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 992 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 992 days (2.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,742 days (7.5 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1603-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.7.
  Slide TCGA-24-1603-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 8; Percent necrosis: 12; Percent stromal cells: 0.
  Slide TCGA-24-1603-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 95; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-24-1603-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 12: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,742 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,742 days; disease-free interval: event (new tumor event after initially disease-free), 992 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 992 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1603-01A-01D-0497-01): tumor purity 0.96, ploidy 1.74, whole-genome doublings 0.
